Gene-level copy-number profile of tumor specimen ALCH-B1S8-TTP1-A from ALCHEMIST case ALCH-B1S8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.3 years (29,708 days).
Specimen ALCH-B1S8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e5975ff-327e-40e3-b0d7-b195577a2a35.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1S8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/558e74e0-0637-471c-aae1-a4783a479f22

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 3,754; copy number 2: 54,301; copy number 3: 813; copy number 4: 7; copy number 5: 3; copy number 6: 2; copy number 8: 2; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,684,766–180,686,546, 1 gene: LINC02222.
- chr7:101,205,977–101,238,820, 3 genes: PLOD3, ZNHIT1, CLDN15.
- chr7:140,645,829–140,646,126, 1 gene (within-gene range 0–2): RN7SL771P.
- chr17:3,636,459–3,663,103, 2 genes (within-gene range 0–1): CTNS, AC027796.4.
- chr17:3,672,199–3,696,240, 1 gene (within-gene range 0–1): P2RX5.
- chr17:7,281,718–7,288,257, 2 genes (within-gene range 0–3): SLC2A4, AC003688.2.
- chr19:13,104,902–13,117,567, 1 gene: TRMT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,833,270–143,840,256, 2 genes, copy number 8: AC234917.1, AC234917.2.
- chr9:136,844,415–136,860,799, 3 genes, copy number 5–6 (within-gene range 2–6): AJM1, PHPT1, MAMDC4.
- chr11:392,614–404,908, 1 gene, copy number 15: PKP3.
- chr11:565,660–568,457, 2 genes, copy number 5: MIR210HG, MIR210.

Autosomal genes at a single copy (total copy number 1): 916. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
